TCGA case TCGA-04-1638 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c75c915f-ef4b-4c19-8ace-995e6c6015fd

Demographics
Sex at birth: female; Race: black or african american; Age at index: 57 years; Vital status: Dead; Days to death: 1,686 days (4.6 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 57.5 years (20,987 days); Year of diagnosis: 2002; Method of diagnosis: Surgical Resection; FIGO stage: Stage IV; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 193 days; Number of cycles: 8; Treatment dose: 2,990 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 193 days; Number of cycles: 8; Treatment dose: 11,400 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 17 days; Days to treatment end: 193 days; Number of cycles: 8; Treatment dose: 968 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel + Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 346 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 614 days (1.7 years).
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 58.3 years (21,285 days); Days to diagnosis: 298 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (3 entries)
- Day 298 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 298 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 1,686 days (4.6 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-04-1638-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-04-1638-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 2.
- Sample TCGA-04-1638-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.4; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Tumor resection.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 3, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 6: Pharmaceutical therapy drug name: Gemcitibine.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,686 days; disease-specific survival: no event (censored), 1,686 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 298 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-04-1638-01A-01D-0577-01): tumor purity 0.92, ploidy 3.47, whole-genome doublings 1.
